Somatic mutation profile of tumor specimen TCGA-CE-A484-01A (aliquot TCGA-CE-A484-01A-11D-A23U-08) from TCGA case TCGA-CE-A484, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.8 years (13,815 days).
Specimen TCGA-CE-A484-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be1cad6c-d847-4eed-877d-1cc00898ac6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A484-10A (Blood Derived Normal), aliquot TCGA-CE-A484-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e28f65d-ac34-4bc4-85cc-5821bd78e98a

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD16A | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as COSV65451805; called by muse, mutect2, varscan2
- BDP1 | c.5794C>G p.P1932A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as COSV62431309; called by muse, mutect2, varscan2
- CHEK2 | c.686A>G p.N229S (on ENST00000382580 / NM_001005735.2; = p.N186S on NM_007194.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as rs369223840, CM138121; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- PINK1 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs777060019, COSV58631130; called by muse, mutect2, varscan2
- PPID | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100306938, COSV56987823; called by muse, mutect2, varscan2
- PSG2 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV61544951; called by muse, mutect2, varscan2
- SH2D2A | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63884828; called by muse, mutect2
- SRPX | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs146651232, COSV59438651; called by muse, mutect2, varscan2
- TFE3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV59946972; called by muse, mutect2, varscan2
- ZNF75D | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV66132708; called by muse, mutect2, varscan2
- ZSWIM8 | c.3878A>G p.N1293S (on ENST00000605216 / NM_001242487.2; = p.N1298S on NM_015037.3) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55214425; called by muse, mutect2, varscan2
- DPYD | c.2175G>A p.K725= | Silent (SNP) | VAF 13/248 reads (5%) | catalogued as COSV64597399; called by muse, mutect2
- HLA-B | c.654C>T p.I218= | Silent (SNP) | VAF 62/134 reads (46%) | catalogued as COSV69521283; called by muse, mutect2, varscan2
- MAGEB6 | c.510C>T p.A170= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs746794376, COSV66872259; called by muse, mutect2, varscan2
- SOWAHB | c.1149C>T p.R383= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs1368906255, COSV57554473; called by muse, mutect2, varscan2
